Somatic mutation profile of tumor specimen MP2PRT-PAPBLU-TBP1-A (aliquot MP2PRT-PAPBLU-TBP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PAPBLU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,877 days).
Specimen MP2PRT-PAPBLU-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68db2b0b-aa33-4115-977f-0e859ea990c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPBLU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPBLU-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84dff931-7d27-4d1d-9909-c9eb20d56b04

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACHE | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.441); catalogued as rs1030385619, COSV53822038; called by muse, mutect2
- ZFYVE19 | c.994C>T p.R332* (on ENST00000355341 / NM_001077268.2; = p.R322* on NM_032850.5) | Nonsense Mutation (SNP) | VAF 37/285 reads (13%) | catalogued as rs376725467; called by muse, mutect2, varscan2
- SAE1 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 22/504 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2
- ZC3H15 | c.827G>A p.R276K | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ADRA1A | c.1386C>T p.N462= | Silent (SNP) | VAF 30/302 reads (10%) | catalogued as rs201746874; called by muse, mutect2, varscan2
- KIAA0319 | c.219C>T p.F73= | Silent (SNP) | VAF 49/539 reads (9%) | catalogued as rs560298185, COSV65496456; called by muse, mutect2
